Somatic mutation profile of tumor specimen TARGET-20-PARTXH-09A (aliquot TARGET-20-PARTXH-09A-04D) from TARGET case TARGET-20-PARTXH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,386 days).
Specimen TARGET-20-PARTXH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b969e6c-62be-427c-a30a-e97f9439edbe.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARTXH-14A (Bone Marrow Normal), aliquot TARGET-20-PARTXH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78457dc2-2f56-4753-a4cb-0bb5f57aa537

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as rs121907909, CM971596, COSV60066326; ClinVar: pathogenic; called by muse, varscan2
- CEBPA | c.934_936dup p.Q312dup | In Frame Ins (INS) | VAF 16/35 reads (46%) | catalogued as COSV57198430; called by mutect2, varscan2
- WT1 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as CM041493, CM920718, CM982050, COSV60065677, COSV60065800, COSV60069955; called by muse, varscan2
